Somatic mutation profile of tumor specimen TCGA-SP-A6QK-01A (aliquot TCGA-SP-A6QK-01A-11D-A35I-08) from TCGA case TCGA-SP-A6QK, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 46.3 years (16,923 days).
Specimen TCGA-SP-A6QK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d415aff3-0e4c-4de0-aa23-a3469ab40ae3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SP-A6QK-10A (Blood Derived Normal), aliquot TCGA-SP-A6QK-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27df266f-df3e-4761-8b62-b43d66793dac

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RET | c.1900T>C p.C634R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs75076352, CM930644, CM941241, CM941242, COSV60685975, COSV60686093, COSV60686416; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FAT1 | c.10294G>A p.D3432N | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs554538206, COSV71675452, COSV71675824; called by muse, mutect2
- RET | c.1543T>A p.C515S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.13); catalogued as rs1275123049; called by muse, varscan2
- SVEP1 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs751874490, COSV57044169; called by muse, mutect2, varscan2
- IL13RA1 | c.542A>G p.Q181R | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- TRAV8-2 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ZNF484 | c.1356del p.K452Nfs*116 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- BBS7 | c.732T>C p.I244= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- KCTD5 | c.198G>A p.P66= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs780283657, COSV57064056, COSV57066069; called by muse, mutect2, varscan2
- KLK12 | c.540C>T p.I180= | Silent (SNP) | VAF 62/198 reads (31%) | called by muse, mutect2, varscan2
